Surgical pathology report (de-identified scan), TCGA case TCGA-61-1915, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1915-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGECTOMY AND OOPHORECTOMY –

- A. POORLY DIFFERENTIATED, MIXED ENDOMETRIOID AND PAPILLARY ADENOCARCINOMA OF THE OVARY, SIZE 7.0 X 4.5 X 3.0 CM.
- B. FOCI OF ENDOMETRIOSIS AND MACROCALCIFICATIONS.
- C. FALLOPIAN TUBE WITH MESONEPHRIC DUCT REMNANTS, NEGATIVE FOR TUMOR.

PART 2: OVARY AND FALLOPIAN TUBE, LEFT, SALPINGECTOMY AND OOPHORECTOMY –

- A. POORLY DIFFERENTIATED, MIXED ENDOMETRIOID AND PAPILLARY ADENOCARCINOMA OF THE OVARY, SIZE 9.0 X 6.0 X 4.5 CM.
- B. PERIOVARY ADHESION INVOLVED BY TUMOR.
- C. FALLOPIAN TUBE WITH OVARY ADHESION AND MESOTHELIAL PROLIFERATION, NEGATIVE FOR TUMOR.

PART 3: PELVIC PERITONEUM, BIOPSY –

FIBROFATTY TISSUE WITH HEMORRHAGE AND METASTATIC ADENOCARCINOMA.

PART 4: UTERUS, TOTAL ABDOMINAL HYSTERECTOMY –

- A. LATERAL ADHESION OF UTERUS WITH METASTATIC ADENOCARCINOMA.
- B. PERITUBAL ADHESION WITH METASTATIC ADENOCARCINOMA.
- C. CHRONIC CYSTIC CERVICITIS WITH SQUAMOUS METAPLASIA.
- D. PROLIFERATIVE ENDOMETRIUM.
- E. ADENOMYOSIS.

PART 5: PERIAORTIC LYMPH NODES, BIOPSY –

FIBROFATTY TISSUE FREE OF TUMOR, NO LYMPH NODES IDENTIFIED. NEGATIVE FOR TUMOR.

PART 6: EXTERNAL, ILIAC LYMPH NODE, LEFT, BIOPSY –

ONE LYMPH NODE NEGATIVE FOR TUMOR.

PART 7: INTERNAL, ILIAC LYMPH NODE, LEFT, BIOPSY –

FIBROFATTY TISSUE WITH NERVE BUNDLES, FREE OF TUMOR.

PART 8: OBTURATOR LYMPH NODE, LEFT, BIOPSY –

ONE LYMPH NODE NEGATIVE FOR TUMOR.

PART 9: COMMON ILIAC LYMPH NODE, RIGHT, BIOPSY –

ONE LYMPH NODE NEGATIVE FOR TUMOR.

PART 10: PARAAORTIC NODE, RIGHT, BIOPSY –

ONE LYMPH NODE NEGATIVE FOR TUMOR.

PART 11: EXTERNAL NODE, RIGHT, BIOPSY –

- A. ONE LYMPH NODE NEGATIVE FOR TUMOR.
- B. FIBROADIPOSE TISSUE FREE OF TUMOR.

PART 12: INTERNAL NODES, RIGHT, BIOPSY –

ONE LYMPH NODE NEGATIVE FOR TUMOR.

PART 13: OBTURATOR NODES, RIGHT, BIOPSY –

FOUR LYMPH NODES NEGATIVE FOR TUMOR.

PART 14: OMENTUM, BIOPSY –

FIBROFATTY TISSUE WITH MESOTHELIAL PROLIFERATION, FREE OF TUMOR.

PART 15: PELVIC FAT WALL, RIGHT, BIOPSY –

FIBROFATTY VASCULARISED TISSUE WITH CHRONIC INFLAMMATION, FREE OF TUMOR.

PART 16: PERITONEAL SIDEWALL, LEFT, BIOPSY –

FIBROFATTY TISSUE AND MUSCLE WITH CHRONIC INFLAMMATION, FREE OF TUMOR.

PART 17: DIAPHRAGM, BIOPSY –

SKELETAL MUSCLE AND FASCIA WITH CHRONIC INFLAMMATION, FREE OF TUMOR.

[page 2 of 2]
- A. Laterality 3
1. Right 2. Left 3. Bilateral
- B. Procedure: 4
1. Cystectomy 4. TAH with salpingo-oophorectomy
2. Salpingo-oophorectomy 5. Other
3. Bilateral salpingo-oophorectomy
- C. Tumor size (maximum dimension): 7.0 cm and 4.0 cm
- D. Histologic type: 1,6
1. Papillary serous tumor, ☐ 12. Undifferentiated Carcinoma
2. Papillary serous carcinoma 13. Small cell carcinoma
3. Mucinous tumor, ☐ 14. Mature teratoma
4. Mucinous carcinoma 15. Immature teratoma
5. Endometrioid tumor, ☐ 16. Dysgerminoma
6. Endometrioid carcinoma 17. Embryonal carcinoma
7. Clear cell tumor, ☐ 18. Yolk sac tumor
8. Clear cell carcinoma 19. Granulosa cell tumor, Juvenile
9. Brenner tumor, ☐ 20. Granulosa cell tumor, adult
10. Malignant Brenner tumor 21. Malignant lymphoma
11. Malignant mixed Müllerian tumor 22. Others
- E. Histologic Grade: 3
1. Well 2. Moderate 3. Poorly differentiated
- F. Vascular Invasion: 1 1. Yes 2. No
- G. Tumor capsule: 1 1. Intact 2. Ruptured
- H. Surface implants: 1
1. Invasive 2. Non-invasive 3. Not present
- I. Surface implants:
11. Uterus: 1 1. Yes 2. No
12. Fallopian tubes: 2 1. Yes 2. No
13. Omentum: 2 1. Yes 2. No
14. Peritoneal metastasis beyond the pelvis: No
1. Microscopic 2. Less than 2 cm. 3. More than 2 cm.
- J. Associated other lesion: 1
1. Endometriosis.
2. Abnormalities of surface epithelium or surface epithelial inclusion.
3. Others.
- K. Malignant cells in ascites or peritoneal washing: 1 1. Yes 2. No
- L. Nodes Involved: 0
L1. Number of positive lymph nodes: 0
L2. Total number of lymph nodes examined: 10
L3. Pelvic: Right: # positive/total # Left: # positive/total #
L4. Obturator: Right: 0/4 positive/total # Left: 0/1 positive/total #
L5. Common iliac: Right: 0/1 positive/total # Left: 0/1 positive/total #
L6. External iliac: Right: 0/1 positive/total # Left: # positive/total #
L7. Para-aortic: Right: 0/1 positive/total # Left: # positive/total #
L8. Inguinal: Right: Internal node: 0/1 positive/total # Left: # positive/total #
- M. Extracapsular lymph node spread 2 1. Yes 2. No
- N. TNM Stage: nT 2C N 0 M X
- O. FIGO Stage: 2C

Source: NCI Genomic Data Commons file 5d24e94d-cdad-419a-8551-ccd979b95e96 (TCGA-61-1915.1C305700-D86F-449A-A556-02F32484DDA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).